Gene-level copy-number profile of tumor specimen HTMCP-03-06-02110-01B from CGCI case HTMCP-03-06-02110, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 44.8 years (16,353 days).
Specimen HTMCP-03-06-02110-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5a352df1-1892-4a7f-a6c4-f9708ab22027.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02110-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/addb0b28-998d-4dd8-aa52-a0edcde7facf

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 330; copy number 2: 19,994; copy number 3: 23,736; copy number 4: 11,843; copy number 5: 1,362; copy number 6: 65; copy number 7: 3; copy number 9: 696; copy number 10: 364.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,063 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:209,367,662–209,432,838, 3 genes, copy number 7: LINC01698, MIR205HG, MIR205.
- chr3:135,925,891–195,620,233, 966 genes, copy number 9–10 (broad region; genes not listed).
- chr3:195,720,884–198,123,232, 94 genes, copy number 9 (within-gene range 3–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 309. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
